Somatic mutation profile of tumor specimen TCGA-FG-A4MW-01A (aliquot TCGA-FG-A4MW-01A-11D-A26M-08) from TCGA case TCGA-FG-A4MW, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Frontal lobe; Tumor grade: G3; Age at diagnosis: 63.2 years (23,077 days).
Specimen TCGA-FG-A4MW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41d94cad-80d9-45f5-bc0e-ad29da14b50b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A4MW-10A (Blood Derived Normal), aliquot TCGA-FG-A4MW-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6424389-7bbc-408f-b0b1-66978943d0f4

The open-access MAF lists 78 somatic variants for this specimen: 48 protein-altering or splice-affecting, 30 silent.
By variant classification: Missense Mutation 39, Silent 30, Frame Shift Del 3, Splice Site 2, Translation Start Site 1, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.3458A>C p.D1153A | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54038017; called by muse, mutect2, varscan2
- ACSL1 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV55666863; called by muse, mutect2, varscan2
- ADAM28 | c.2060G>A p.R687Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs780931542, COSV56106079; called by muse, mutect2, varscan2
- ADAMTS15 | c.2558C>T p.A853V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs765064754, COSV54503421; called by muse, mutect2, varscan2
- AQP4 | c.32+1G>T p.X11_splice | Splice Site (SNP) | VAF 24/124 reads (19%) | catalogued as rs750966881, COSV101270487; called by muse, mutect2, varscan2
- ARSG | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs185381597; called by muse, mutect2, varscan2
- ASMT | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs189062200, COSV101172411; called by muse, mutect2, varscan2
- ATF7IP2 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV61095585; called by muse, mutect2, varscan2
- CABIN1 | c.973A>G p.S325G | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV54089882; called by muse, mutect2, varscan2
- CARD11 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1237589286, COSV62716241; called by muse, mutect2, varscan2
- COLEC11 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52591374; called by muse, mutect2, varscan2
- CTIF | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs373686942; called by muse, mutect2, varscan2
- CTTNBP2 | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV50485634; called by muse, mutect2, varscan2
- EFCAB3 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); catalogued as COSV59504272; called by muse, mutect2, varscan2
- EGFR | c.934G>T p.G312W | Missense Mutation (SNP) | VAF 3461/3814 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV51814881; called by muse, mutect2, varscan2
- ENPEP | c.586C>A p.L196M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV54458092; called by muse, mutect2, varscan2
- FOXN1 | c.1825G>C p.G609R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV56884512; called by muse, mutect2, varscan2
- FSIP2 | c.16820G>A p.G5607D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58101134; called by muse, mutect2, varscan2
- GOLGA5 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as COSV50836259; called by muse, mutect2, varscan2
- GRIA1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs759117420, COSV53589188; called by muse, mutect2, varscan2
- ISM1 | c.1367A>G p.K456R | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV52608643; called by muse, mutect2, varscan2
- KANK3 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759934875, COSV56847675; called by muse, mutect2, varscan2
- MISP | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV53122545; called by muse, mutect2
- PEAR1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1305973574, COSV52776176; called by muse, varscan2
- PHGDH | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV65584939; called by muse, mutect2, varscan2
- PLCG2 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63867809, COSV63872285; called by muse, mutect2, varscan2
- PRUNE2 | c.7771_7774del p.L2591Qfs*12 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs1194973681; called by mutect2, pindel, varscan2
- PRX | c.4216_4217del p.K1406Vfs*81 | Frame Shift Del (DEL) | VAF 33/162 reads (20%) | catalogued as rs779727296; called by mutect2, pindel, varscan2
- PTCD1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52863470, COSV52868145; called by muse, mutect2, varscan2
- PTEN | c.30C>G p.S10R | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs1564801689, COSV64308242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD15 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.583); catalogued as rs201418471, COSV53628147; called by muse, mutect2, varscan2
- SERPINA3 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV67587269; called by muse, mutect2, varscan2
- SERPINB7 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760065556, COSV60535993; called by muse, mutect2, varscan2
- SLC22A25 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as rs370074611, COSV100123444; called by muse, mutect2, varscan2
- SLC8A3 | c.2236G>A p.V746M (on ENST00000381269 / NM_183002.3; = p.V744M on NM_033262.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53693025; called by muse, mutect2, varscan2
- STOML1 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as rs777996238, COSV57551519; called by mutect2, varscan2
- SYT9 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV59625736; called by muse, mutect2, varscan2
- TBL1Y | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV60733158; called by muse, mutect2, varscan2
- TIAM2 | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1562325804, COSV59705067; called by muse, mutect2, varscan2
- TLN2 | c.4025+1G>A p.X1342_splice | Splice Site (SNP) | VAF 10/21 reads (48%) | catalogued as COSV60890065, COSV60896437; called by muse, mutect2, varscan2
- ZNF226 | c.1645C>T p.H549Y | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56198088; called by muse, mutect2, varscan2
- ZNF236 | c.4964G>A p.R1655Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs766225440, COSV53498697, COSV99470323; called by muse, mutect2, varscan2
- ZNF540 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs374512088; called by muse, mutect2, varscan2
- ZNF713 | c.860A>C p.H287P (on ENST00000633730 / NM_001366796.2; = p.H300P on NM_182633.3) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV101448765; called by muse, mutect2, varscan2
- AADACL2 | c.886_889del p.V296Ifs*36 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- IGKV1D-17 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SAP130 | c.2602_2604del p.V868del | In Frame Del (DEL) | VAF 29/98 reads (30%) | called by mutect2, pindel, varscan2
- ZC3H11A | c.1756dup p.A586Gfs*61 | Frame Shift Ins (INS) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- APMAP | c.246G>A p.L82= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- ASPN | c.444C>T p.T148= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs569274142, COSV65016742; called by muse, mutect2, varscan2
- ATP8B3 | c.3372C>T p.C1124= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV59549217; called by mutect2, varscan2
- C6 | c.2517C>T p.D839= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs567176554, COSV54707923; called by muse, mutect2, varscan2
- CDK14 | c.438T>C p.Y146= (on ENST00000380050 / NM_001287135.2; = p.Y128= on NM_012395.3) | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs1196448406, COSV56053698; called by muse, mutect2, varscan2
- DDX42 | c.33G>A p.K11= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as COSV63791536; called by muse, mutect2, varscan2
- FLNB | c.849C>T p.S283= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as rs770546915, COSV55897326; called by muse, mutect2, varscan2
- HAPLN1 | c.1041C>T p.V347= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as COSV57152370; called by muse, mutect2, varscan2
- HECTD4 | c.7842C>T p.A2614= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs778906389, COSV66400564; called by muse, varscan2
- HLA-DPB1 | c.525C>A p.I175= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV69604315, COSV69604343; called by muse, mutect2, varscan2
- HSD17B2 | c.570C>T p.A190= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs767788961, COSV52278778; called by muse, mutect2, varscan2
- KIAA1210 | c.42C>T p.H14= | Silent (SNP) | VAF 51/69 reads (74%) | catalogued as rs763058290, COSV68180496; called by muse, mutect2, varscan2
- LCE2A | c.195C>T p.G65= | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as rs61812675, COSV64227204; called by muse, mutect2, varscan2
- MAGEA11 | c.1173C>T p.H391= | Silent (SNP) | VAF 71/101 reads (70%) | catalogued as rs376112940, COSV60757527; called by muse, mutect2, varscan2
- MAK16 | c.838C>A p.R280= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV62453814; called by muse, mutect2, varscan2
- MYO5C | c.2533C>T p.L845= | Silent (SNP) | VAF 58/106 reads (55%) | catalogued as rs774686743, COSV55912594; called by muse, mutect2, varscan2
- NLRC4 | c.2535C>T p.H845= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV61595062; called by muse, mutect2, varscan2
- NTN3 | c.1044C>T p.R348= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV53549016; called by muse, mutect2, varscan2
- OR4A16 | c.264C>T p.I88= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as rs763768417, COSV59041879; called by muse, mutect2, varscan2
- OR7C2 | c.51C>T p.F17= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as rs776824671, COSV50180571; called by muse, mutect2, varscan2
- PIEZO2 | c.8028A>T p.S2676= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV53294878; called by muse, mutect2, varscan2
- PLCG2 | c.975G>A p.S325= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs764831936, COSV63874774, COSV63877081; called by muse, mutect2, varscan2
- PTCH2 | c.1476C>T p.G492= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs569864866, COSV64713751; called by muse, mutect2, varscan2
- RBMS3 | c.966C>T p.D322= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV56170923; called by muse, mutect2, varscan2
- RIN2 | c.642C>T p.F214= (on ENST00000255006 / NM_001242581.1; = p.F165= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs759898074, COSV54787621; called by muse, mutect2, varscan2
- SEC11C | c.111C>T p.F37= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as rs573800787, COSV55312438; called by muse, mutect2, varscan2
- SNRPA | c.450G>A p.A150= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs773592729, COSV54681785, COSV54683005; called by muse, mutect2, varscan2
- TIMP2 | c.543G>A p.K181= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as COSV53163494; called by muse, mutect2, varscan2
- WFS1 | c.2538C>T p.S846= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs753674557, COSV56991999; called by muse, mutect2, varscan2
- ZBTB40 | c.3579G>A p.E1193= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs1429326507, COSV65146533; called by muse, mutect2, varscan2
